Somatic mutation profile of tumor specimen 0DF0AM from CCDI case PBBRBP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.4 years (890 days).
Specimen 0DF0AM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b3937fd-b224-4bbd-8811-fe8230916051.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF0AQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08003411-387a-4ea9-ac24-ae8abcc2636d

The open-access MAF lists 33 somatic variants for this specimen: 28 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Nonsense Mutation 3, Silent 3, Splice Site 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 233/271 reads (86%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- CDH2 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 89/707 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs754165315, COSV52276234, COSV52294881; called by muse, mutect2, varscan2
- CSMD2 | c.3244G>T p.G1082C | Missense Mutation (SNP) | VAF 96/525 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53922969; called by muse, mutect2, varscan2
- OR10G8 | c.295C>A p.Q99K | Missense Mutation (SNP) | VAF 329/372 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101461856; called by muse, mutect2, varscan2
- OR51V1 | c.880A>C p.I294L | Missense Mutation (SNP) | VAF 277/1401 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV58315131; called by muse, mutect2, varscan2
- PDZD7 | c.2819G>A p.R940Q | Missense Mutation (SNP) | VAF 398/920 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs556216049; called by muse, mutect2, varscan2
- PKD1L1 | c.931C>G p.R311G | Missense Mutation (SNP) | VAF 367/780 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV99220888; called by muse, mutect2, varscan2
- POU6F2 | c.1879G>C p.E627Q | Missense Mutation (SNP) | VAF 273/1455 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV68867963; called by muse, mutect2, varscan2
- PRKCG | c.1133C>G p.A378G | Missense Mutation (SNP) | VAF 310/372 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV54723320, COSV54725798; called by muse, mutect2, varscan2
- SLC12A5 | c.1402G>A p.V468I (on ENST00000454036 / NM_001134771.2; = p.V445I on NM_020708.5) | Missense Mutation (SNP) | VAF 571/950 reads (60%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV54800861; called by muse, mutect2, varscan2
- TCTN2 | c.1445A>G p.E482G | Missense Mutation (SNP) | VAF 546/1338 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.798); catalogued as rs1305099981; called by muse, mutect2, varscan2
- TTC16 | c.1663C>A p.L555M | Missense Mutation (SNP) | VAF 464/526 reads (88%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as COSV60161310; called by muse, mutect2, varscan2
- AHNAK2 | c.2853A>C p.E951D | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ARAP1 | c.3806T>A p.L1269Q (on ENST00000393609 / NM_001040118.2; = p.L1024Q on NM_015242.4) | Missense Mutation (SNP) | VAF 92/255 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- C3AR1 | c.103T>A p.L35I | Missense Mutation (SNP) | VAF 348/836 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.255); called by muse, varscan2
- CCDC30 | c.2447G>T p.G816V (on ENST00000340612; = p.G773V on NM_001080850.3) | Missense Mutation (SNP) | VAF 171/830 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- COL4A2 | c.3287C>T p.T1096I | Missense Mutation (SNP) | VAF 150/598 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ESRRB | c.102C>A p.S34R | Missense Mutation (SNP) | VAF 217/469 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- FAM133B | c.260C>A p.S87* | Nonsense Mutation (SNP) | VAF 214/1251 reads (17%) | called by muse, mutect2, varscan2
- HABP2 | c.1073T>C p.L358P | Missense Mutation (SNP) | VAF 383/876 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LEPR | c.2671A>T p.K891* | Nonsense Mutation (SNP) | VAF 599/1346 reads (45%) | called by muse, mutect2, varscan2
- MALRD1 | c.3208T>A p.C1070S | Missense Mutation (SNP) | VAF 358/1573 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MC3R | c.852C>A p.Y284* | Nonsense Mutation (SNP) | VAF 235/2728 reads (9%) | called by muse, mutect2
- MUC19 | c.749-1G>C p.X250_splice | Splice Site (SNP) | VAF 447/837 reads (53%) | called by muse, mutect2, varscan2
- OR2A12 | c.223A>G p.S75G | Missense Mutation (SNP) | VAF 485/1123 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- OR2A2 | c.362G>T p.R121M | Missense Mutation (SNP) | VAF 185/1077 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SDCCAG8 | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 306/1593 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ZNF438 | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 330/713 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COG4 | c.496T>C p.L166= | Silent (SNP) | VAF 257/652 reads (39%) | called by muse, mutect2, varscan2
- FBXL16 | c.810G>A p.L270= | Silent (SNP) | VAF 14/157 reads (9%) | catalogued as COSV60964801; called by muse, mutect2
- ZBTB11 | c.2274A>G p.Q758= | Silent (SNP) | VAF 319/736 reads (43%) | catalogued as rs1377174394; called by muse, mutect2, varscan2
- B4GALNT3 | c.539-49A>G | Intron (SNP) | VAF 110/474 reads (23%) | called by mutect2, varscan2
- CLLU1 | n.928T>A | RNA (SNP) | VAF 216/918 reads (24%) | called by muse, mutect2, varscan2
